MMRF case MMRF_2457 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bbe20c05-d319-435b-b78b-7e47280357d6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.7 years (19,237 days); ISS stage: III; Days to last known disease status: 671 days (1.8 years); Days to last follow up: 671 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 9 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 40 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 331 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 40 days; Days to treatment end: 331 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 40 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 198 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 223 days; Days to treatment end: 331 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 369 days (1.0 years); Days to treatment end: 369 days (1.0 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 369 days (1.0 years); Days to treatment end: 369 days (1.0 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 371 days (1.0 years); Days to treatment end: 371 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 587 days (1.6 years); Days to treatment end: 699 days (1.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -34 (ECOG 0): M Protein 2.02 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 118 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.078 mg/dL; Immunoglobulin G 28.5 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 5.82 µg/mL; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.93 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 6.16 mmol/L; C-Reactive Protein 0.02 mg/dL.
- Day 79 (ECOG 0): M Protein 0.73 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 101 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.108 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 6.1 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 5.56 mmol/L.
- Day 163 (ECOG 0): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.144 mg/dL; Immunoglobulin G 5.44 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 13.4 ×10⁹/L; Absolute Neutrophil 10.2 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 4.46 mmol/L.
- Day 226 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.679 mg/dL; Immunoglobulin G 4.55 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 6.44 mmol/L.
- Day 324 (ECOG 0): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 84 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 4.84 mmol/L.
- Day 422 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.938 mg/dL; Immunoglobulin G 5.74 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 4.51 mmol/L.
- Day 520: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 6.39 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 5.7 g/dL; Glucose 4.62 mmol/L.
- Day 587 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.735 mg/dL; Immunoglobulin G 6.91 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 4.84 mmol/L.
- Day 671 (ECOG 0): M Protein 0.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.079 mg/dL; Immunoglobulin G 6.72 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 6.93 mmol/L.

Other clinical attributes
- Day -34: Weight: 105 kg; Height: 190 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2457_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -34 days.
- Sample MMRF_2457_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -34 days.
